Somatic mutation profile of tumor specimen MP2PRT-PAVRGM-TMP1-A (aliquot MP2PRT-PAVRGM-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVRGM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,175 days).
Specimen MP2PRT-PAVRGM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c04f6243-4df9-42c1-a6e5-27f6a0a0401b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRGM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRGM-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ad0d80f-e282-4322-8a7f-dc6dbee76ce4

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH10 | c.10835C>T p.T3612M (on ENST00000409039; = p.T3551M on NM_207437.3) | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553611508, COSV68990706; called by mutect2, varscan2
- ZNRF4 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 35/486 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs777701903, COSV55774484; called by muse, mutect2
